Gene-level copy-number profile of tumor specimen TCGA-EB-A5SH-06A from TCGA case TCGA-EB-A5SH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.9 years (22,985 days).
Specimen TCGA-EB-A5SH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6a1bb484-46cd-4f20-958f-4c68d6c942a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5SH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/761f4ca9-cdd2-4bbf-a435-c2615bc07546

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 709; copy number 2: 12,855; copy number 3: 21,356; copy number 4: 16,483; copy number 5: 4,489; copy number 6: 3,081; copy number 7: 421; copy number 8: 65; copy number 9: 80; copy number 10: 44; copy number 11: 32; copy number 12: 3; copy number 13: 10; copy number 14: 73; copy number 18: 2; copy number 20: 21; copy number 23: 45; copy number 28: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5SH-06A-11D-A30W-01): tumor purity 0.73, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,905,790–181,906,467, 1 gene: CCNHP1.
- chr15:38,139,595–38,226,897, 1 gene (within-gene range 0–2): AC087473.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 837 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–4,175,899, 1 gene, copy number 13: EEF1DP6.
- chr1:5,478,736–5,494,674, 3 genes, copy number 14: Z98259.3, Z98259.2, Z98259.1.
- chr1:13,696,070–15,118,043, 4 genes, copy number 7–18 (within-gene range 2–18): AL359771.2, PRDM2, KAZN, RNU6-1265P.
- chr1:14,338,825–14,777,727, 3 genes, copy number 7–8 (within-gene range 2–8): KAZN-AS1, TBCAP2, AL031293.1.
- chr1:17,066,761–17,246,007, 4 genes, copy number 10 (within-gene range 3–10): PADI2, LINC02783, AL590644.2, PADI1.
- chr1:17,372,196–18,748,866, 16 genes, copy number 7 (within-gene range 3–7): PADI6, RCC2-AS1, RCC2, ARHGEF10L, LINC02810, ACTL8, AL357509.1, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1, KLHDC7A, DYNLL1P3, AL031737.1, PAX7.
- chr1:21,424,625–21,669,363, 8 genes, copy number 10 (within-gene range 3–10): NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10, ALPL, LINC02596, RAP1GAP.
- chr1:26,826,688–27,886,685, 54 genes, copy number 7–14 (within-gene range 3–14): ZDHHC18, SFN, GPN2, AL034380.1, GPATCH3, NUDC, NR0B2, KDF1, RPL12P13, AL356390.1, OSTCP2, TRNP1, TENT5B, SLC9A1, AL590640.2, CHCHD3P3, NPM1P39, SNRPEP7, AL590640.1, WDTC1, Y_RNA, FO393419.3, TMEM222, RNU6-48P, ACTG1P20, SYTL1, MAP3K6, FCN3, CD164L2, FO393419.1, GPR3, WASF2, FO393419.2, BX293535.1, AHDC1, FGR, AL031729.1, LINC02574, IFI6, AL445490.1, RNU6-949P, CHMP1AP1, RNU6-424P, AL020997.5, FAM76A, AL020997.1, RPEP3, STX12, AL020997.2, AL020997.3, RNU6-1245P, AL020997.4, PPP1R8, THEMIS2.
- chr1:28,505,943–28,769,775, 21 genes, copy number 20: RCC1, SNHG3, SNORA73A, SNORA73B, PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A, TAF12, RAB42, LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1, YTHDF2.
- chr1:43,838,622–44,031,467, 12 genes, copy number 8: MIR6079, SHMT1P1, ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2, CCDC24, SLC6A9.
- chr1:109,062,486–109,238,182, 9 genes, copy number 13 (within-gene range 2–13): TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1.
- chr6:5,918,564–6,321,013, 6 genes, copy number 7: RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683.
- chr6:6,347,081–6,347,381, 1 gene, copy number 7: SNAPC5P1.
- chr6:10,492,223–21,232,404, 159 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:22,085,544–22,302,826, 4 genes, copy number 7: RN7SKP240, NBAT1, AL359694.1, PRL.
- chr6:34,279,679–35,091,406, 22 genes, copy number 11 (within-gene range 5–11): NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1.
- chr6:37,170,152–37,819,218, 17 genes, copy number 8: PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1.
- chr6:38,481,692–38,715,217, 5 genes, copy number 10: BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1.
- chr6:43,307,134–43,369,647, 1 gene, copy number 7 (within-gene range 6–7): ZNF318.
- chr6:43,328,134–45,377,953, 61 genes, copy number 7 (broad region; genes not listed).
- chr6:45,421,079–45,422,005, 1 gene, copy number 7: AL096865.1.
- chr6:47,231,532–47,477,572, 4 genes, copy number 8: TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1.
- chr6:49,273,600–58,438,364, 152 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:67,538,899–70,436,584, 101 genes, copy number 9–23 (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 14: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:77,066,961–78,582,156, 44 genes, copy number 9–28: CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 12: AP002768.1.
- chr11:84,887,207–85,021,655, 5 genes, copy number 11: AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.
- chr11:88,408,179–89,065,945, 5 genes, copy number 10: GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P.
- chr11:98,565,074–98,683,735, 2 genes, copy number 12: AP003038.1, AP003715.1.
- chr11:103,675,994–104,252,651, 6 genes, copy number 10: AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1.
- chr12:12,452,103–12,829,981, 16 genes, copy number 10: AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47.
- chr12:13,000,451–13,142,521, 4 genes, copy number 9 (within-gene range 5–9): AC023790.2, AC023790.1, FAM234B, GSG1.
- chr12:13,683,542–13,683,886, 1 gene, copy number 9: RN7SKP162.
- chr12:24,810,024–26,335,856, 40 genes, copy number 7 (within-gene range 5–7): BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3.
- chr12:38,906,451–38,996,882, 2 genes, copy number 9: CPNE8-AS1, AC018448.2.
- chr12:70,515,870–70,920,738, 5 genes, copy number 11 (within-gene range 3–11): PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:97,272,692–97,598,415, 15 genes, copy number 7: LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6.
- chr12:127,451,346–127,636,488, 9 genes, copy number 9: AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411.
- chr12:128,244,506–128,707,915, 6 genes, copy number 9: AC061709.1, TMEM132C, AC061709.3, MIR3612, AC023595.1, AC090424.1.

Autosomal genes at a single copy (total copy number 1): 709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
